Surgical pathology report (de-identified scan), TCGA case TCGA-23-1028, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1028-01A (Primary Tumor).

[page 1 of 7]
SURGICAL
PATIENT:
Hospital
Date

PATH #:
A/S:
Rec:
Col:

Location
Patholog:
Assistant:
Attending MD:
Ordering MD:
Copies To:

DIAGNOSIS: **ADDENDUM AND CORRECTIONS, *

Due to a computer glitch, an incomplete preliminary report was inadvertently finalled before the diagnoses for specimens 16-20 were transcribed. The diagnoses for specimens 16-20 have now been entered. These additional diagnoses and corrections of typographical errors in the preliminary diagnosis (for specimens 1-15) and in the gross descriptions are indicated in bold type. There are no significant changes in the diagnoses (previously issued) for specimens 1-15.

1. OMENTUM, OMENECTOMY:
- Metastatic mullerian-derived carcinoma (see comment)
2. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:
- Primary ovarian adenocarcinoma, mixed epithelial types, grade III (see comment)
- Ovary measures 9.5 cm in maximum dimension and is nearly totally replaced by carcinoma
- Carcinoma also involves paraovarian and paratubal adnexal ligaments
- Fallopian tube is involved by carcinoma; tumor in the fallopian tube involves the serosa, subserosa, muscular wall, and mucosa
- Lymphovascular invasion by carcinoma is present
3. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:
- Primary ovarian adenocarcinoma, mixed epithelial types, grade III (see comment)
- Ovary measured about 7.2 cm in maximum dimension and is subtotally replaced by carcinoma
- Carcinoma also involves the serosal surface of the ovary, paraovarian and paratubal ligamentous soft tissues
- Fallopian tube is positive for carcinoma; carcinoma involves the serosal surface and subserosa of the fallopian tube and also involves the mucosa of the

(continued on next page)□

- fallopian tube
- Lymphovascular invasion by carcinoma is present
- Ovary also shows a hemorrhagic follicular-derived cyst
- Fallopian tube also shows acute and chronic salpingitis with features suggestive of so-called follicular salpingitis in some areas
- 4. PERI-INTESTINAL FIBROADIPOSE TISSUE, RECTOSIGMOID, EXCISION:
- Metastatic mullerian-derived carcinoma (see comment)

[page 2 of 7]
5. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Metastatic mullerian-derived carcinoma involving external aspect of endocervix, outer muscular wall of endocervix, anterior peritoneal soft tissue reflection, external aspect/serosal surface of anterior and posterior lower uterine segments, outer aspect of muscular wall of anterior lower uterine segment, serosa and subserosa of anterior uterine corpus
- Lymphovascular invasion by carcinoma is present
- No evidence of carcinoma at surgical margins
- Endometrium with proliferative features
- Focal so-called superficial adenomyosis
- Cervix with chronic and minimal acute inflammation, reserve cell hyperplasia, squamous metaplasia, and nabothian cysts
- Vaginal cuff mucosa with minimal chronic inflammation

6. MESENTERY OF SIGMOID COLON, BIOPSY:

- Metastatic mullerian-derived carcinoma (see comment)

7. RECTUM, "RECTAL TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)
- No large intestinal tissue identified

8. SOFT TISSUE, RIGHT PELVIS, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)

9. SOFT TISSUE, CUL DE SAC PERITONEUM, EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)

10. SOFT TISSUE, RIGHT SIDEWALL, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)

11. LYMPH NODES, LEFT PELVIC, EXCISION:

- Two lymph nodes with reactive lymphoid (follicular and parafollicular) hyperplasia and sinus histiocytosis
- No evidence of metastatic carcinoma (0/2)

12. SOFT TISSUE, PERITONEUM, BIOPSY:

- Metastatic mullerian-derived carcinoma (see comment)

13. LYMPH NODES, RIGHT OBTURATOR, EXCISION:

- One of two lymph nodes positive for metastatic mullerian-derived carcinoma (1/2) (see comment)
- Lymph nodes also show reactive lymphoid (follicular and parafollicular) hyperplasia and sinus histiocytosis

14. VERMIFORM APPENDIX, APPENDECTOMY:

(continued on next page)□

- Acute and chronic inflammation of serosa and subserosa of appendix and partial fibrous obliteration of lumen of appendix (at the tip)
- No evidence of metastatic carcinoma

15. SMALL INTESTINE, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)

16. SOFT TISSUE, RIGHT DIAPHRAGM, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma (see comment)

17. LIVER, "SURFACE", BIOPSY:

- Metastatic mullerian-derived carcinoma involving fibrous tissue/liver capsule (see comment)

[page 3 of 7]
- Tiny fragment of subcapsular liver parenchyma showing marked thermal/cautery artifacts
18. SOFT TISSUE, FALCIFORM LIGAMENT, BIOPSY:
- Perivascular margination of leukocytes in submesothelial tissue
- No evidence of metastatic carcinoma
19. SOFT TISSUE, RIGHT HEMIDIAPHRAGM, BIOPSY:
- Metastatic mullerian-derived carcinoma (see comment)
20. SOFT TISSUE, LEFT PERITONEUM, 'TUMOR', EXCISION:
- Metastatic mullerian-derived carcinoma (see comment)

COMMENT: Both ovaries are enlarged and subtotally replaced by carcinoma. By convention, the neoplasm is considered to be a bilateral primary ovarian neoplasm; however, the involvement of the mucosa of both fallopian tubes by carcinoma (in addition to the outer aspects of the fallopian tubes which are involved tumor), the possibility of synchronous primary tubal neoplasms are also considered. The carcinoma consists of multiple components, including serous carcinoma, carcinoma with transitional or pseudotransitional features, endometrioid carcinoma, anaplastic carcinoma, and a small subpopulation of tumor cells exhibiting cytoplasmic clearing. Tumor-associated necrosis is present in both ovaries, as well as in multiple other metastatic sites. Secondary acute and chronic inflammatory changes are present in both ovaries and many of the metastatic sites. Lymphovascular invasion by carcinoma is present in most of the involved sites. Adhesions and secondary reactive mesothelial change are noted in many of the involved sites. The preliminary pathologic findings were communicated to on

=====

HISTORY: Pelvic mass; ovarian cancer

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM

Labeled with the patient's name, designated 'omentum', and received
(continued on next page)□

fresh in the JR for frozen section diagnosis, subsequently fixed in formalin is a 230 gram piece of omentum that measures 30.0 x 11.0 x 2.0 cm. Approximately 46% of the omentum is replaced by multifocal infiltrating process. The largest mass measures 13.0 x 5.5 x 2.0 cm. A sample of this mass is frozen for frozen section diagnosis. The smallest lesion is 0.5 x 0.3 x 0.3 cm.

Representative sections.

- A. Frozen section control - 1
- B. Sections of largest and smallest tumor - 2

2: LEFT ADNEXA

Labeled with the patient's name, designated 'left adnexa', and received in formalin is a 150 gram specimen consisting of ovary and fallopian tube. The ovary measures 9.5 x 7.0 x 6.0 cm and is entirely replaced by a solid cystic mass (approximately 50% solid). The cysts range from 0.5 to 2.5 cm and contain serosanguineous fluid. The solid areas have papillary structures and some of the papillae protrude from the capsular surface of the ovary. No normal ovary is identified. The fallopian tube measures 10.0 cm in length and 0.5 to 1.5 cm in diameter. The fimbriated end is not visible. The distal two-thirds of the fallopian tube are replaced by tumor.

Representative sections.

[page 4 of 7]
- C,D. Cystic portions of ovarian tumor - 1 each
- E. Ovary with tumor including external papillary tumor - multiple
- F. Paraovarian tumor - 1
- G-H. Ovary and tumor - 1 each
- I. Fallopian tube with tumor - 1

Additional representative sections (submitted on

QQ. Fallopian tube with tumor - 1

RR. Fallopian tube with tumor - 1

3: RIGHT ADNEXA

Labeled with the patient's name, designated "right adnexa", and received in formalin is a 53 gram specimen consisting of ovary and fallopian tube. The ovary measures 7.2 x 5.0 x 3.0 cm and is completely replaced by a solid and cystic tumor that is approximately 30% cystic and 70% solid. The cyst contains serous fluid. The fallopian tube measures 6.0 cm in length and 0.5 to 1.7 cm. The distal two-thirds are occupied by tumor. The solid areas of the tumor have papillary appearance and there are papillae that are located on the serosal surface of the fallopian tube and the external side of the ovarian capsule. No ovarian stroma is identified, but there is one small corpus luteum next to the capsule (cassette K). One of the cysts has purulent material and measures 3.0 x 1.5 x 1.5 cm.

Representative sections.

J. "Purulent" ovarian cyst - 1

K. Fallopian tube with tumor and adherent ovary with tumor - 1

L. Ovarian and paraovarian tumor - 1

M. Fallopian tube with tumor - 3

Additional representative sections (submitted on :

SS. Fallopian tube with tumor and paratubal cyst - 2

SS. Fallopian tube with tumor - 1

4: RECTOSIGMOID

(continued on next page)□

Labeled with the patient's name, designated "rectosigmoid", and received in formalin is a 2.5 x 2.0 x 0.9 cm piece of adipose tissue partially replaced approximately 30% with white tumor that measures 1.4 x 0.6 x 0.6 cm.

Representative section.

N. 1

5: UTERUS

Labeled with the patient's name, designated "uterus", and received in formalin is a 120 gram total hysterectomy specimen. The uterus is symmetric. The uterus measures 9.5 cm from fundus to ectocervix, 5.2 cm from cornu and cornu and 4.0 cm from anterior to posterior. The uterine serosa is smooth in the superior one-third of the specimen. The remainder is replaced with tumor, mainly in the anterior aspect. The cervix is about 3.2 cm long and has a maximum diameter of 3.4 cm in the ectocervical region. Attached to the ectocervix there is an up to 1.0 cm long cuff of normal vaginal mucosa. The mucosa lining the ectocervix is pale pink and smooth. The external cervical os is 1.1 cm in diameter and slit-like. The uterus is incised on both sides. The cervical transformation zone is patent. The endocervical canal is 2.5 cm long and lined by slightly bumpy mucosa. Cut sections of the cervix reveal no significant findings. The endometrial cavity is 4.5 cm long and up to 2.5 cm in width. The endometrium is unremarkable. The endometrial lining is pink, slightly hemorrhagic and measures 0.1 to 0.2 cm in thickness. The muscular uterine wall has a maximum thickness of 2.8 cm. The myometrium is unremarkable.

Representative sections.

O,P. Posterior cervix, one section bisected - 1 each

[page 5 of 7]
- Q. Lower uterine segment - 1
- R-S. Posterior uterine wall, bisected - 1 each
- T-U. Anterior cervix, bisected - 1 each
- V. Anterior lower uterine segment - 1
- W. Anterior uterine corpus - 1

6: SIGMOID MESENTERIC TUMOR

Labeled with the patient's name, designated "sigmoid mesenteric tumor", and received in formalin are four pieces of tan-white soft tissue that range from 0.4 to 1.4 cm in length.

Entire embedded.

X. 4

7: RECTAL TUMOR

Labeled with the patient's name, designated "rectal tumor", and received in formalin are two pieces of tan-brown soft tissue that measure 0.4 and 1.0 cm in greatest dimension.

Entirely embedded.

Y. 2

8: RIGHT PELVIC TUMOR

Labeled with the patient's name, designated "right pelvic tumor", and received in formalin are two pieces of tan-brown soft tissue that measure 1.5 x 1.2 x 0.6 cm and 2.0 x 1.2 x 0.7 cm.

Representative sections.

Z. 2

9: CUL DE SAC PERITONEUM

Labeled with the patient's name, designated "cul-de-sac peritoneum",

(continued on next page)□

and received in formalin is a 3.8 x 2.7 x 0.5 cm piece of tan-brown soft tissue that is almost completely replaced by tumor.

Representative sections.

A2. 2

10: RIGHT SIDE WALL TUMOR

Labeled with the patient's name, designated "right side wall tumor", and received in formalin is a 1.4 x 0.7 x 0.4 cm piece of white-tan soft tissue. Bisected and entirely embedded.

B2. 2

11: LEFT PELVIC LYMPH NODE

Labeled with the patient's name, designated "left pelvic lymph node", and received in formalin is a 2.0 x 1.7 x 0.7 cm piece of fibroadipose tissue containing two lymph nodes that measure 1.7 and 1.6 cm. The lymph nodes are bisected and entirely embedded.

C2. One lymph node bisected - 2

D2. One lymph node bisected - 2

12: PERITONEUM BIOPSY

Labeled with the patient's name, designated "peritoneal biopsy", and received in formalin is a 3.5 x 1.0 x 0.3 cm piece of brown tissue. It is serially sectioned and entirely embedded.

E2. 4

13: RIGHT OBTURATOR LYMPH NODE

Labeled with the patient's name, designated "obturator lymph node", and received in formalin is a 3.0 x 2.5 x 1.0 cm aggregate of fibroadipose tissue containing two lymph nodes that measure 1.5 and 2.1 cm in largest dimensions. The largest node is grossly metastatic. Only one section of it is embedded. The other node is entirely embedded.

F2. One lymph node, bisected and entirely embedded - 2

G2. Grossly metastatic lymph node one section - 1

[page 6 of 7]
14: APPENDIX

Labeled with the patient's name, designated "appendix", and received in formalin is a 2.8 cm long appendix that measures 0.5 to 0.8 cm in diameter. There is a portion of adipose tissue attached to the appendix that measures 2.8 x 1.5 x 1.0 cm. No tumor is identified grossly in the specimen. The appendix is entirely embedded.

H2. 3

I2. 4

15: SMALL BOWEL TUMOR

Labeled with the patient's name, designated "small bowel tumor", and received in formalin are three pieces of tan-white soft tissue that measure 0.2, 0.5 and 0.7 cm in largest dimension. Entirely embedded.

J2. 3

16: RIGHT DIAPHRAGMATIC TUMOR

Labeled with the patient's name, designated "right diaphragmatic tumor", and received in formalin are three pieces of tan-yellow pink soft tissue that range from 0.5 to 2.0 cm in largest dimension. Representative sections.

K2. 5

(continued on next page)□

17: LIVER SURFACE

Labeled with the patient's name, designated "liver surface", and received in formalin are two pieces of tan-brown soft tissue that measure 0.6 x 0.3 x 0.2 cm and 1.4 x 0.3 x 0.2 cm. Entirely embedded.

L2. 2

18: FALCIFORM LIGAMENT

Labeled with the patient's name, designated "falciform ligament", and received in formalin is a 6.0 x 6.0 x 2.0 cm piece of adipose tissue. No tumor is evident grossly.

Representative sections.

M2-N2. 2 each

19: RIGHT HEMIDIAPHRAGM

Labeled with the patient's name, designated "right hemidiaphragm", and received in formalin are two portions of a fibrous membrane that measure 2.0 x 1.5 x 0.7 cm and 5.5 x 1.0 x 0.5 cm. Small white nodules that measure up to 0.3 cm in largest dimensions are present in the specimen.

Representative sections.

O2. 4

20: LEFT PERITONEAL TUMOR

Labeled with the patient's name, designated "left peritoneal tumor", and received in formalin is a 1.4 x 1.2 x 0.6 cm piece of soft tan-brown tissue with a white nodularity similar to the other tumors. The largest nodule measures 0.4 cm in diameter. Entirely embedded.

P2. 3

Gross dictated by

[page 7 of 7]
OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

1. OMENTUM:

- High grade adenocarcinoma
- Tumor taken for research

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

2,3. BILATERAL ADNEXA:

- Tumor taken for research

4. UTERUS:

(continued on next page)□

- Serosal tumor
- Smooth endometrium with no gross tumor

Special Studies: Frozen Section

See Also:

Pathologist

I, , the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled:

I, the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this amended report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file 28f5f6ab-8b77-458f-83c9-7fad5b4e28f8 (TCGA-23-1028.CCD0A1B3-DE92-473C-AA1B-8EE25DE408A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).